Surgical pathology report (de-identified scan), TCGA case TCGA-3G-AB0O, project TCGA-THYM (Thymoma), tissue source site MD Anderson Cancer Center, specimen TCGA-3G-AB0O-01A (Primary Tumor).

[page 1 of 3]
Accession: [REDACTED]
Specimen Date/Time:

DIAGNOSIS

(A) THYMOMA:

Thymoma with focal capsular invasion. (See comment)
Margin of resection is free of tumor.

(B) 4R LYMPH NODE:

Fragments of lymph node, no tumor present.

(C) 2R LYMPH NODE:

Fragments of lymph node, no tumor present.

COMMENT

Immunohistochemical studies done on tumor sections show a strong reactivity from pan keratin and keratin 5/6 in the epithelial component of the tumor. These findings support the above diagnosis.

GROSS DESCRIPTION

(A) THYMOMA - One pink-yellow adipose fibrous tissue (9.5 x 5.8 x 3.8 cm), including one firm, well circumscribed mass (3.5 x 3.0 x 2.9 cm) with the pink-gray, fleshy cut surface with focal hemorrhage. The mass is found in the capsule without invading of the adipose tissue. The external surface, the mass is pink-red, smooth and glistening and inked with blue ink. A portion of the tumor and normal tissue is submitted for Tumor Bank, representatively submitted.

INK CODE: Blue - external surface.

SECTION CODE: A1-A5, representative sections of the tumor; A6, tumor with adjacent adipose tissue; A7, representative section of the fibrous tissue.

(B) 4 R LYMPH NODE - Multiple pale-gray fibroadipose tissue (3.2 x 2.5 x 0.8 cm in aggregate) with four possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 0.6 x 0.4 x 0.4 cm and multiple black - dark brown tissue fragments.

SECTION CODE: B1, four possible lymph nodes; B2, three black-dark brown tissue fragments.

(C) 2R LYMPH - Two pink-gray fibroadipose tissue (2.9 x 1.4 x 0.7 cm in aggregate) with one possible lymph node measuring 1.4 x 0.9 x 0.5 cm. The specimen is entirely submitted.

SECTION CODE: C1, one lymph node serially sectioned; C2, remainder of the fibrous tissue.

CLINICAL HISTORY

Thymoma.

SNOMED CODES

T-C8000, M-85800

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

ICD-0-3
Thymoma, Type B1, malignant 8583/3
path
Thymoma NOS, malignant 8580/3
Site: Thymus C57.9
JWS 6/5/14

[page 2 of 3]
Page: 2

Accession: [REDACTED]
Specimen Date/Time:

M

-----END OF REPORT-----

Pw TSS dx discrepancy form;
TCGA tumor is Thymoma, type B1.

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	B1	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Histologic subtype was not done at initial pathologic diagnosis. Reviewing Pathologist has re-reviewed the case slide and provided the WHO subtype	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file ebda5f46-2ffa-4deb-ab6b-59264b97dd39 (TCGA-3G-AB0O.6FAA90E1-454A-4862-B6B1-30A3892DECFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).